Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XE-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, left temporal mass #1, #2 and anterior, biopsies and CUSA: Anaplastic oligoastrocytoma, astrocytic dominant (WHO grade III)

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to p53 and MIB-1. p53 is positive in tumor cells. MIB-1 labeling index is moderate. The findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the

1CD-0-3
oligoastrocytoma, anaplastic 9382/3
Site: brain, temporal lobe C71-2
fw
10/23/12

Preliminary Frozen Section Consultation:

A. Brain, left temporal mass #1, smears: Low-grade glioma.

Intraoperative cytologic smear(s) interpretation performed by:

[page 2 of 2]
M.D., Ph.D.

Gross Description:

A. Received fresh labeled "left temporal brain mass" is a 2.7 x 2.3 x 1.3 cm portion of brain. Smears prepared. All submitted. Grossed by

B. Received fresh labeled "left anterior temporal brain mass" is a 1.8 x 1.6 x 0.7 cm aggregate of white-tan tissue. All submitted for permanent sections only. Grossed by

C. Received fresh within a CUSA trap labeled "CUSA specimen trap - left temporal brain mass" is a 3.5 x 3.0 x 0.7 cm aggregate of tumor. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left temporal brain mass

- 1 Lt temporal brain 1
- 2 Lt temporal brain 2
- 3 Lt temporal brain 3
- 4 Lt temporal brain 4

Part B: Left anterior temporal brain mass

- 1 Lt ant temporal brain 1
- 2 Lt ant temporal brain 2

Part C: Cusa Left anterior temporal brain mass

- 1 Lt ant temporal mass 1
- 2 Lt ant temporal mass 2

END OF REPORT

Source: NCI Genomic Data Commons file ef631ff0-d6c9-405c-b96a-4d9966dedad0 (TCGA-DB-A4XE.1D110C27-320E-4C5D-A8E1-9DF4F257543D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).